Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24O, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24O-01A (Primary Tumor).

lw 4/25/11

Final Diagnosis

Breast, left, modified radical mastectomy: Multifocal lobular carcinoma with focal ductal features, Nottingham grade I (of III) forming two separate masses, 5.3 x 2.7 x 1.4 cm and 1.2 x 1.0 x 1.0 cm in the inferior and medial breast respectively (AJCC pT3). A biopsy cavity is identified adjacent to the tumor in the medial breast. Lymphovascular space invasion is not seen. The remaining breast parenchyma shows adenosis and duct ectasia. The nipple shows no diagnostic abnormalities. Margins of resection are negative for tumor (closest margin is anterior/inferior, free by at least 0.8 cm). Multiple (6 of 17) left axillary lymph nodes are involved by metastatic lobular carcinoma (AJCC pN2). Focal extracapsular extension is also present.

Her-2/NEU has been ordered on paraffin embedded tissue.

1CD-0-3

Carcinoma, infiltrating duct and lobular, nos 8522/3

Site: breast, nos c50.9 lw
4/25/11

Source: NCI Genomic Data Commons file eac2519f-c87a-4653-92f5-36c67515bb42 (TCGA-AR-A24O.887F0E3A-DC70-4CD4-AAAF-3C613195D895.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).